Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3SX, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3SX-01A (Primary Tumor).

[page 1 of 3]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

[REDACTED]

Specimen(s) Received

1. Parathyroid: ? Parathyroid tissue for QS
2. Thyroid: Total thyroid - stitch left superior pole
3. Thyroid: Left lateral central compartment
4. Thyroid: Left medial central compartment

ICD-O-3
Carcinoma, papillary, thyroid
Site: thyroid, NOS
8260/3
C73.9 4-3-12 CP

Diagnosis

1. No pathological diagnosis: Parathyroid (site not specified) biopsy
2. Multifocal bilateral papillary carcinoma, dominant left 4.4 cm classical variant involving resection margin:
Thyroid, total thyroidectomy specimen
3. Metastatic papillary thyroid carcinoma: Lymph node, 1 (left lateral central compartment) dissection specimen
4. Metastatic papillary thyroid carcinoma: Lymph nodes, 2 of 3 (left medial central compartment) dissection specimen

Synoptic Data

Procedure:	Total thyroidectomy with central compartment dissection
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe: 3.9 cm 1.7 cm 1.0 cm Left lobe: 4.6 cm 2.9 cm 1.9 cm Isthmus +/- pyramidal lobe: 1.5 cm 1.6 cm 0.6 cm Central compartment: 4 cm 3.5 cm

ICD-O-3 Discrepancy		X

[page 2 of 3]
[REDACTED]

[REDACTED]

1. The specimen labeled with the patient's name and as "1A" contains a piece of tissue that measures 0.3 x 0.1 x 0.1 cm. It is frozen for intraoperative consultation.

[page 3 of 3]
Surgical Pathology Consultation Report

2. The specimen labeled with the patient's name and as _____ consists of a thyroid gland that is oriented with a suture and weighs 24.8 g. The right lobe measures 3.9 cm SI x 1.7 cm ML x 1.0 cm AP, the left lobe measures 4.6 cm SI x 2.9 cm ML x 1.9 cm AP and the isthmus measures 1.5 cm SI x 1.6 cm ML x 0.6 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands and/or no lymph nodes are identified grossly. The external surface is painted with blue dye. The left lobe contains a well delineated nodule that measures 4.4 cm SI x 2.2 cm ML x 1.8 cm AP and the right lobe contains a well delineated nodule that measures 0.8 cm SI x 0.7 cm ML x 0.6 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted in toto.

2A-D right lobe, superior to inferior

2E isthmus

2F-N left lobe, superior to inferior

3. The specimen labeled with the patient's name and as "Left Lateral Central Compartment" consists of a piece of fibrofatty tissue measuring 3.0 x 1.6 x 0.4 cm. received in 10% buffered formalin.

3A submitted in toto.

4. The specimen labeled with the patient's name and as "Left Medial Central Compartment" consists of a piece of fibrofatty tissue measuring 3.5 x 2.4 x 0.3 cm. received in 10% buffered formalin.

4A submitted in toto.

Quick Section Diagnosis

1. Parathyroid: Parathyroid tissue identified.

Surgeon called

Source: NCI Genomic Data Commons file 9a93522e-47f3-4886-aea6-912139ded102 (TCGA-EM-A3SX.C4114C5A-DE73-499B-BED6-FC8F9976C3E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).